Surgical pathology report (de-identified scan), TCGA case TCGA-23-1024, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1024-01A (Primary Tumor).

[page 1 of 3]
Path #:
Pathologist:
Assistant:
Date of Procedure:
Date Received:

UUID:1CCES978-6A4D-427A-9875-47617F6A4258

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. RIGHT TUBE AND OVARY:

- High-grade papillary serous carcinoma
- Fallopian tube focal epithelial hyperplasia

B. LEFT FALLOPIAN TUBE AND OVARY:

- High-grade papillary serous carcinoma

C. UTERUS AND CERVIX:

- Atrophic endometrium
- Leiomyoma
- Metastatic high-grade papillary serous carcinoma in uterine serosa
- Adenomyosis
- Endometriosis in fallopian tube

D. OMENTUM:

- Metastatic papillary serous carcinoma, high grade

E. OMENTUM #2:

- Metastatic papillary serous carcinoma, high grade

HISTORY: Ovarian cancer/pelvic mass

MICROSCOPIC:

See diagnosis.

SPECIAL STUDIES:

IMMUNOSTAINS:

GROSS:

A. RIGHT TUBE AND OVARY

Labeled with the patient's name, labeled "right tube and ovary", and received fresh in the Operating Room for intraoperative frozen consultation and subsequently fixed in formalin and is a 650 gram right salpingo-oophorectomy specimen and is a 15.0 x 14.0 x 7.5 cm focally disrupted, ovarian mass with delicate serosal fibrous adhesions and attached fibrous connective tissue. The serosal surface of the mass is lobulated and smooth and elsewhere has papillary surfaces with collapsed cystic areas with smooth linings and containing serous fluid. There is a small focal area of residual ovary identified measuring 7.0 x 2.5 cm. The mass has almost entirely replaced the ovarian tissue. Previous incision has been made into the specimen in the Operating Room and tissue submitted for frozen section diagnosis. Sectioning through the mass reveals numerous solid semifirm areas with lobulated glistening surfaces. Elsewhere there are papillary friable areas. Multilocular cystic areas are also identified with a

Patient Case(s):

[page 2 of 3]
PATH #:

small amount of what is believed to be residual ovary. Attached fallopian tube measures 5.0 cm in length x 0.5 cm in diameter and contains fimbriated end. The serosa is smooth and otherwise unremarkable. On section, there is a pinpoint lumen with a 0.2 cm wall thickness. No gross luminal obstructions are identified. Representative sections submitted.

- A1. Frozen section control for FS#1 (specimen A) - 1
- A2-A6. Most thickened solid areas of tumor - 2 each
- A7, A8. Cystic areas of tumor - 2 each
- A9. Possible residual ovary - 2
- A10. Proximal mid and distal fallopian tube - 3

B. LEFT TUBE AND OVARY

Labeled with the patient's name, labeled "left tube and ovary", and received in formalin and is left salpingo-oophorectomy specimen which includes a 3.5 x 2.5 x 2.5 cm cystic ovary. The serosa is relatively smooth and is focally adhered to the mesovarium tissues. The ovary is serially sectioned to reveal a single unilocular cyst measuring 2.0 x 2.0 x 1.5 and contains a serosanguineous fluid. The cyst lining contains gross papillary excrescences. There are focal areas of pale tan necrosis with possible residual ovary noted at one end. The cut surfaces of the tumor appear consistent with that of the tumor identified in the right ovary. Attached fallopian tube measures 5.5 cm in length and ranges from 0.4 up to 0.8 cm in diameter and contains a focally hemorrhagic fimbriated end. Thin-walled, smooth-lined fluid-filled paratubal cyst is identified measuring 2.5 x 2.0 x 2.0 cm and contains a straw-colored serous fluid. On section, there is a 0.4 cm lumen with a 0.4 to 0.5 cm wall thickness. The fallopian tube is somewhat edematous but does not contain any gross luminal obstructions. Representative sections submitted.

- B1, B2, and B3. Solid area of tumor to cyst - 3, 3, 1
- B4. Possible residual ovary - 1
- B5. Proximal mid and distal fallopian tube to paratubal cyst and tumor - 3

C. UTERUS AND CERVIX

Labeled with the patient's name, labeled "uterus and cervix", and received in formalin is a 50 gram hysterectomy specimen received without attached bilateral fallopian tubes or ovaries. The uterus is symmetric with the exception of the bulging subserosal nodule and measures 7.0 cm from fundus to the ectocervix, 3.5 from cornu to cornu and 3.0 cm from the anterior surface to the posterior surface. The serosa is pink-tan smooth and glistening. The cervix measures 3.0 cm long and has a maximum diameter of 3.0 cm in the ectocervical region. The mucosa lining the ectocervix is smooth and unremarkable. There is a small portion of vaginal cuff measuring 0.5 cm in length along the posterior aspect. The external cervical os is slit-like measuring 0.6 cm in length. The uterus has been incised on both sides. The cervical transformation zone is distinct. The endocervical canal is 2.0 cm long and lined by pink-tan rugose mucosa and contains thickened mucous material. Cut sections of the cervix reveal mucus-filled cysts measuring up to 0.2 to 0.3 cm. The endometrial cavity is 3.0 cm long by 1.5 cm in width. The endometrium shows pink-tan smooth appearing mucosa which has an average thickness of 0.2 cm and is grossly uninvolved by any suspicious lesions. Within the uterus there are two well-circumscribed pink-white leiomyoma measuring 0.8 and 3.0 cm in greatest dimension. The smaller leiomyoma is located in the intramural region and the larger in the subserosal region. On section, the leiomyoma contain typical pink-white bulging cut surfaces with a whorled configuration with no areas of calcification, degeneration or hemorrhage seen. The uterine muscular wall has an average thickness of 1.3 cm. The myometrium is pink-tan and slightly trabecular. Please note that additional sections are submitted of the fallopian tube stump and are serially sectioned from the cauterized resection margin to the intrauterine aspect of the fallopian tube. The cauterized resection margins are inked black. Please note that the cauterized margin on the right side has been severely clamped and the fallopian tube opening is difficult to identify. Representative sections submitted.

- C1. Anterior cervix - 1
- C2. Posterior cervix - 1
- C3. Anterior uterine corpus - 1
- C4. Posterior uterine corpus - 1
- C5. Smaller intramural leiomyoma, bisected - 2
- C6. Representative sections of subserosal leiomyoma - 3

[page 3 of 3]
PATH #:

C7-C9. Sequentially cut sections of right fallopian tube from distal cauterized resection margin to more proximal intrauterine fallopian tube aspect - 3, 1, 1

C10-C12. Fallopian tube sequentially sectioned from distal cauterized resection margin to proximal intrauterine fallopian tube aspect - 2, 2, 1

D. OMENTUM #1

Labeled with the patient's name, labeled "omentum #1", and received in formalin and is a 12.5 x 6.5 x 1.0 cm portion of lobulated yellow fatty omental tissue containing delicate surface fibrous adhesions. On section, gross tumor implants are identified within the omental fat ranging in size from 0.2 up to 1.0 cm in greatest dimension. Representative sections submitted.

D1. 3

E. OMENTUM #2

Labeled with the patient's name, labeled "omentum #2", and received in formalin and is a 15.0 x 7.0 x 2.0. On section, there is a pink-tan firm tumor implant measuring 1.0 x 0.8 x 0.5 cm.

E1. Representative sections - 3

Gross dictated by

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

SPECIMEN A: RIGHT OVARY AND FALLOPIAN TUBE (FS1 OF LARGE TUMOR MASS):

- Adenocarcinoma consistent with mullerian/ovarian origin
- Portion of tumor procured unfixed for research.

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by

Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Electronically signed.

Source: NCI Genomic Data Commons file 9ba9f305-c76f-466e-93cb-46f1043ff0e8 (TCGA-23-1024.1CCE5978-6A4D-427A-9875-47617F6A4258.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).